Gene-level copy-number profile of tumor specimen TCGA-5M-AATA-01A from TCGA case TCGA-5M-AATA, project TCGA-COAD (Colon Adenocarcinoma).
Specimen TCGA-5M-AATA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.b3e35145-c013-4465-b2d3-773db827f1f0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-5M-AATA-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6514ca87-8809-4b53-9a1c-bceca2d4e178

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 67; copy number 1: 5,972; copy number 2: 45,822; copy number 3: 4,746; copy number 4: 1,318; copy number 5: 1,894.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-5M-AATA-01A-31D-A40O-01): tumor purity 0.43, ploidy 3.94, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 67 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:110,289,233–113,488,823, 45 genes (within-gene range 0–2): TMEM232, MIR548F3, AC008650.1, SLC25A46, AC008782.1, BCLAF1P1, AC010395.1, AC010395.2, TSLP, AC008572.1, WDR36, AC010468.2, RPS3AP21, CAMK4, AC010468.1, AC010275.1, STARD4, STARD4-AS1, HMGN1P13, AC008967.1, NREP, RN7SKP57, HMGN1P14, NREP-AS1, EPB41L4A, EPB41L4A-AS1, SNORA13, AC010261.1, AC010261.2, AC104126.1, AC010265.1, EPB41L4A-DT, HMGB3P16, AC137549.1, LINC02200, APC, CBX3P3, RNU6-482P, AC008575.1, SRP19, REEP5, XBP1P1, ZRSR2P1, DCP2, MCC.
- chr18:38,655,209–40,247,367, 17 genes: AC100781.1, RN7SKP182, RNU6-706P, MIR924HG, AC011139.1, RPL7AP66, MIR924, AC099845.1, MIR5583-2, MIR5583-1, RNU6-1242P, LINC01901, LINC01902, AC011266.1, LINC01477, RPL17P45, AC068688.1.
- chr18:68,237,100–68,495,133, 5 genes: AC005909.2, LINC01912, AC022968.1, AC005909.1, AKR1B10P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,894 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:51,961,458–70,104,179, 276 genes, copy number 5 (broad region; genes not listed).
- chr8:70,669,369–145,066,685, 1,158 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr20:30,214,765–32,167,258, 60 genes, copy number 5 (within-gene range 3–5): CFTRP3, LINC01597, AL121762.1, AL121762.2, Y_RNA, FAM242A, FRG1BP, MLLT10P1, 5_8S_rRNA, AC018688.1, ANKRD20A21P, U6, RNA5SP528, DEFB115, DKKL1P1, AL121723.1, DEFB116, RPL31P3, HAUS6P2, RNA5SP480, DEFB117, DEFB118, AL031650.1, DEFB119, DEFB121, DEFB122, DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON, TPX2, AL160175.1, MYLK2, FOXS1, DUSP15, TTLL9, RNU1-94P, PDRG1, XKR7, AL031658.2, AL031658.1, RNA5SP481, CCM2L, RNA5SP482, HCK, TM9SF4, AL049539.1.
- chr20:47,826,969–64,313,132, 400 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,972. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
